TCGA case TCGA-FY-A3NP — Thyroid Carcinoma (TCGA-THCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Thyroid gland; Tissue source site: International Genomics Consortium. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/029da211-9b52-45ad-b0dc-2322da783c9c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 69 years; Vital status: Alive.

Diagnoses (1)
1. Papillary carcinoma, follicular variant: ICD-O-3 morphology code: 8340/3; ICD-10 code: C73; Tissue or organ of origin: Thyroid gland; Site of resection or biopsy: Thyroid gland; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 69.7 years (25,462 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 491 days (1.3 years); Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Measurement unit: Centimeters; Tumor length measurement: 2.
   Treatment given: Treatment type: Radiation, Systemic; Days to treatment start: 180 days; Days to treatment end: 180 days; Treatment dose: 122 mCi; Treatment outcome: Complete Response; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: I-131 Radiation Therapy; Treatment intent type: Adjuvant; Treatment dose: 122 mCi; Pretreatment: rhTSH.
   Treatment given: Treatment type: I-131 Radiation Therapy; Treatment intent type: Adjuvant; Prescribed dose: 121.9; Prescribed dose units: mCi; Pretreatment: rhTSH; Timepoint category: First Treatment.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation, External Beam.

Follow-up (4 entries)
- Days to follow up: 18 days; Disease response: Tumor Free.
- Days to follow up: 491 days (1.3 years); Disease response: Tumor Free.
- Imaging type: CT Scan; Imaging anatomic site: Lymph Node; Timepoint: Preoperative.
- Disease response: Complete Response; Timepoint: Within 3 Months of Surgery.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FY-A3NP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 11 mg.
  Slide TCGA-FY-A3NP-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 85; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-FY-A3NP-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-FY-A3NP-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Submitted tumor site: Thyroid; Histologic diagnosis: Thyroid Papillary Carcinoma - Follicular (>= 99% follicular patterned); Laterality: Right lobe; Lymph nodes preop imaging: Yes; Lymph nodes examined: No.
- Neoplasm dimension: Tumor size width: 2.0.
- Lymph node preoperative assessment diagnostic imaging types: Lymph nodes preop imaging type: CT without contrast.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; I 131 radiation first treatment method: rhTSH; I 131 radiation first treatment dose: 121.9 mCi; I 131 radiation treatment cumulative dose: 121.9 mCi; Radiation therapy xrt method prep: Patient Did Not Receive External Radiation Therapy; Clinical status within 3 mths surgery: No imaging evidence of disease; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 491 days; disease-specific survival: no event (censored), 491 days; disease-free interval: no event (censored), 491 days; progression-free interval: no event (censored), 491 days.
